MMRF case MMRF_1651 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c82d659c-a845-4b01-8bbd-776783c3ccdc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 642 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.2 years (19,793 days); ISS stage: III; Days to last known disease status: 642 days (1.8 years); Days to last follow up: 642 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 633 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 358 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 358 days; Days to treatment end: 379 days (1.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 642.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 90.9 mg/dL; Immunoglobulin G 86.5 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 6.37 µg/mL; Lactate Dehydrogenase 1.7 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 25 g/L; Total Protein 13.6 g/dL; Glucose 4.35 mmol/L; C-Reactive Protein 0.72 mg/dL.
- Day 71 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.68 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 5.83 mmol/L.
- Day 176 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.74 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 274: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.19 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 358: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 2.76 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 607: Serum Free Immunoglobulin Light Chain, Kappa 4.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.5 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 4.19 g/L; Immunoglobulin M 0.47 g/L; Hemoglobin 5.39 mmol/L; Leukocytes 5.4 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Glucose 7.15 mmol/L.

Other clinical attributes
- Day 1: Weight: 100 kg; Height: 185 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1651_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1651_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
